Gene-level copy-number profile of specimen HCM-BROD-0220-C15-85D from HCMI case HCM-BROD-0220-C15, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Esophagus, NOS; Tumor grade: GX; Age at diagnosis: 60.2 years (21,985 days).
Specimen HCM-BROD-0220-C15-85D: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: Adherent Cell Line; Preservation method: Frozen; Passage count: 8.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file d0706c96-38e5-4f87-8014-a3d347b0ef56.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator HCM-BROD-0220-C15-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,719 have no estimate.
https://portal.gdc.cancer.gov/files/3cc7151a-6abd-4ef0-90b6-40cb727b3eab

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 455; copy number 1: 495; copy number 2: 29,744; copy number 3: 21,881; copy number 4: 4,436; copy number 5: 1,051; copy number 6: 173; copy number 7: 293; copy number 8: 14; copy number 12: 12; copy number 16: 78; copy number 21: 54; copy number 22: 38; copy number 23: 2; copy number 27: 34; copy number 29: 78; copy number 35: 7; copy number 39: 36; copy number 101: 7; copy number 144: 6; copy number 158: 3; copy number 162: 5; copy number 164: 2.

Homozygous deletions (total copy number 0; autosomes only): 10 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:12,822,686–12,928,253, 10 genes (within-gene range 0–2): LINC01784, PRAMEF11, PRAMEF30P, HNRNPCL1, PRAMEF2, PRAMEF4, PRAMEF10, PRAMEF7, RNU6-1072P, PRAMEF29P.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 1,893 genes in 15 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:25,242,249–25,338,213, 1 gene, copy number 5 (within-gene range 2–5): RSRP1.
- chr1:25,266,102–25,330,445, 3 genes, copy number 5: AL031432.2, RHD, SDHDP6.
- chr1:143,498,785–143,500,512, 2 genes, copy number 6: AC239859.2, LINC02799.
- chr2:166,403,573–179,861,612, 236 genes, copy number 5–7 (within-gene range 3–7) (broad region; genes not listed).
- chr2:233,059,967–233,586,291, 12 genes, copy number 12: INPP5D, RN7SL32P, ATG16L1, SCARNA5, SCARNA6, SAG, AC013726.1, DGKD, Y_RNA, USP40, PPFIA1P1, UGT1A12P.
- chr5:18,886,622–45,895,970, 344 genes, copy number 6–8 (broad region; genes not listed).
- chr6:60,719,222–61,574,402, 7 genes, copy number 5: GAPDHP41, AL590227.1, AL512427.2, AL512427.1, RBBP4P3, AL356131.1, MTRNR2L9.
- chr7:21,215,537–30,367,689, 189 genes, copy number 5–39 (within-gene range 4–39) (broad region; genes not listed).
- chr8:6,959,289–6,980,080, 3 genes, copy number 5: DEFA9P, DEFA10P, DEFA1.
- chr8:112,222,928–145,066,685, 505 genes, copy number 5–6 (broad region; genes not listed).
- chr13:108,596,152–114,337,626, 116 genes, copy number 5 (broad region; genes not listed).
- chr17:18,390,153–18,400,961, 2 genes, copy number 5: AL353997.5, TBC1D3P4.
- chr17:18,450,244–18,506,313, 6 genes, copy number 5: KRT16P4, AL353997.1, AL353997.4, TNPO1P2, LGALS9C, NOS2P2.
- chr17:37,907,957–41,786,931, 219 genes, copy number 16–164 (broad region; genes not listed).
- chr20:56,248,732–64,327,972, 248 genes, copy number 5 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 495. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
